Somatic mutation profile of tumor specimen MMRF_2700_1_BM_CD138pos (aliquot MMRF_2700_1_BM_CD138pos_T1_KHS5U_L14430) from MMRF case MMRF_2700, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,314 days).
Specimen MMRF_2700_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fbb8b8f-31f2-4d32-aec1-9da163297280.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2700_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2700_1_PB_WBC_C2_KHS5U_L14431; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a71550b-7ecc-4aec-aea5-dd64079fcf48

The open-access MAF lists 91 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 23, Silent 12, Intron 11, 5'UTR 5, Splice Region 1, Splice Site 1, Nonsense Mutation 1, 5'Flank 1, 3'Flank 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP2 | c.2426C>T p.T809M (on ENST00000547588 / NM_001122772.2; = p.T473M on NM_014770.4) | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs747768095; called by muse, mutect2, varscan2
- ARFIP2 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1341783963; called by muse, mutect2, varscan2
- BTK | c.756G>C p.W252C | Missense Mutation (SNP) | VAF 64/68 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as CM983854; called by muse, varscan2
- CCDC158 | c.1826T>G p.L609R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV101187289; called by muse, mutect2, varscan2
- CHD7 | c.8213C>A p.T2738K | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.206); catalogued as COSV71109597; called by muse, mutect2, varscan2
- CLSTN2 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.805); catalogued as rs1047973426; called by muse, mutect2
- DCHS1 | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 133/422 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55030124; called by muse, mutect2, varscan2
- DHRS7C | c.847G>A p.A283T (on ENST00000330255 / NM_001220493.2; = p.A282T on NM_001105571.3) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1308907842, COSV57652697; called by muse, mutect2, varscan2
- DRD4 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs906330178; called by muse, mutect2, varscan2
- ENO2 | c.1134C>G p.D378E | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV57545407; called by muse, mutect2, varscan2
- ERBB4 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.327); catalogued as rs772917832; called by muse, mutect2, varscan2
- FBN1 | c.5060G>T p.C1687F | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM154842; called by muse, mutect2
- FLVCR2 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs1383810834; called by muse, mutect2
- IGHV2-70 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs751573365; called by muse, varscan2
- IGLV3-1 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs371556422; called by muse, varscan2
- IGLV3-1 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774168565; called by muse, varscan2
- MSX1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs781615134; called by muse, mutect2, varscan2
- PAPPA2 | c.2470G>T p.A824S | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100866698, COSV62787417; called by muse, mutect2, varscan2
- RPL11 | c.6+3G>A | Splice Region (SNP) | VAF 83/169 reads (49%) | catalogued as rs776630838; called by muse, mutect2, varscan2
- SCAF1 | c.3084_3101del p.E1034_E1039del | In Frame Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs764348745; called by mutect2, varscan2
- ACSL3 | c.1337G>T p.R446L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADRB2 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- ATP4A | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- BTBD10 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCT2 | c.299C>G p.T100S | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD2 | c.7247-1G>A p.X2416_splice | Splice Site (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- CTSC | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- DMGDH | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- DOP1A | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ECPAS | c.3562C>T p.P1188S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGNBP2 | c.1467A>C p.E489D | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, varscan2
- GRIN3A | c.1709T>C p.I570T | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- H3C7 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 89/353 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LTB | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 320/487 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAP4K3 | c.2044T>G p.Y682D | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLGN1 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 219/335 reads (65%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NMT1 | c.196_199del p.E66Kfs*13 | Frame Shift Del (DEL) | VAF 29/109 reads (27%) | called by pindel, varscan2
- OR52E6 | c.131A>T p.N44I | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABHD13 | c.117G>T p.L39= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2, varscan2
- CCT2 | c.297T>C p.T99= | Silent (SNP) | VAF 37/60 reads (62%) | called by muse, mutect2
- KDM4E | c.573G>A p.E191= | Silent (SNP) | VAF 92/339 reads (27%) | catalogued as COSV71678597; called by muse, mutect2, varscan2
- KRT31 | c.111C>T p.I37= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1487300280; called by muse, mutect2, varscan2
- MTMR4 | c.1884C>T p.S628= | Silent (SNP) | VAF 69/145 reads (48%) | called by muse, mutect2, varscan2
- PLA2G2F | c.21C>T p.A7= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs765332309; called by muse, mutect2, varscan2
- ROGDI | c.99G>A p.Q33= | Silent (SNP) | VAF 62/107 reads (58%) | catalogued as rs1273427204; called by muse, mutect2, varscan2
- SEMA3F | c.2157C>A p.G719= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as COSV50029752; called by muse, mutect2
- TENM2 | c.5793G>A p.V1931= (on ENST00000518659 / NM_001122679.2; = p.V1692= on NM_001080428.3) | Silent (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- TEX13A | c.264C>T p.H88= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- WDR18 | c.489G>A p.A163= | Silent (SNP) | VAF 130/203 reads (64%) | catalogued as rs1328664100; called by muse, mutect2, varscan2
- ZG16B | c.141G>A p.G47= | Silent (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- AGO4 | c.*3390A>C | 3'UTR (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- ANGPTL1 | c.*791T>C | 3'UTR (SNP) | VAF 14/57 reads (25%) | catalogued as rs762641974; called by muse, mutect2, varscan2
- C17orf107 | c.*2003G>A | 3'UTR (SNP) | VAF 184/265 reads (69%) | called by muse, mutect2, varscan2
- CALHM1 | c.*1051dup | 3'UTR (INS) | VAF 61/132 reads (46%) | catalogued as rs1481746042; called by mutect2, varscan2
- CAV2 | c.*9A>G | 3'UTR (SNP) | VAF 77/316 reads (24%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.*374A>G | 3'UTR (SNP) | VAF 46/87 reads (53%) | catalogued as rs1212396292; called by muse, mutect2, varscan2
- CCNC | chr6:99568946 C>A | 5'Flank (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*922A>G | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- CRTAM | c.*185dup | 3'UTR (INS) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- CSMD3 | c.3310+1594T>C | Intron (SNP) | VAF 14/25 reads (56%) | catalogued as rs1203350108; called by muse, mutect2, varscan2
- CUL5 | c.*2732G>A | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- DCXR | c.349-20C>G | Intron (SNP) | VAF 192/298 reads (64%) | called by muse, mutect2, varscan2
- DIXDC1 | c.-56A>C | 5'UTR (SNP) | VAF 10/145 reads (7%) | catalogued as rs903632474, COSV67742607; called by muse, mutect2
- ERLIN2 | c.424+664C>T | Intron (SNP) | VAF 31/58 reads (53%) | catalogued as rs1036288085; called by muse, mutect2, varscan2
- FAR1 | c.*3320G>A | 3'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- FMN1 | c.2161+1701C>A | Intron (SNP) | VAF 89/405 reads (22%) | called by muse, mutect2, varscan2
- FOXP1 | c.*2556A>G | 3'UTR (SNP) | VAF 40/76 reads (53%) | called by muse, varscan2
- FSD1L | c.*2232G>C | 3'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- GRTP1 | c.921+137C>T | Intron (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- IRAK3 | c.134-6165G>A | Intron (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- ITGA9 | c.2434-109A>C | Intron (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- KCNK3 | c.*1035A>C | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- MPRIP | c.123+14796C>G | Intron (SNP) | VAF 33/44 reads (75%) | called by muse, mutect2, varscan2
- MRPS21 | c.-355A>G | 5'UTR (SNP) | VAF 153/242 reads (63%) | called by muse, mutect2, varscan2
- MTMR9 | c.1114-282G>A | Intron (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.*4413C>T | 3'UTR (SNP) | VAF 65/105 reads (62%) | catalogued as rs1277947401; called by muse, mutect2, varscan2
- PARD3 | c.*350A>G | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- PARG | c.2542-110del | Intron (DEL) | VAF 11/19 reads (58%) | catalogued as rs550663040; called by mutect2, varscan2
- PRAMEF14 | c.*318dup | 3'UTR (INS) | VAF 26/119 reads (22%) | called by mutect2, varscan2
- PSMC1 | c.-36A>T | 5'UTR (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.*573C>T | 3'UTR (SNP) | VAF 14/389 reads (4%) | called by muse, mutect2
- REM2 | c.*341C>G | 3'UTR (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- RNF40 | c.*1228T>G | 3'UTR (SNP) | VAF 13/153 reads (8%) | called by muse, mutect2
- SEPTIN5 | c.950+66G>C | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- SERP1 | c.*1412C>G | 3'UTR (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2
- SKIL | c.-542C>G | 5'UTR (SNP) | VAF 7/169 reads (4%) | called by muse, mutect2
- SLC23A2 | c.*2574_*2575insGA | 3'UTR (INS) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- UGT3A1 | c.*2185T>G | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2
- VPS39 | chr15:42159335 A>C | 3'Flank (SNP) | VAF 96/350 reads (27%) | called by muse, mutect2, varscan2
- WDR70 | c.*115G>A | 3'UTR (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- ZBED8 | c.-42C>T | 5'UTR (SNP) | VAF 118/390 reads (30%) | catalogued as rs780479118; called by muse, mutect2, varscan2
